Surgical pathology report (de-identified scan), TCGA case TCGA-AF-2693, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-2693-01A (Primary Tumor).

CGA-AF-2693

SPECIMEN

Sigmoid colon and upper rectum

CLINICAL NOTES

PRE-OP DIAGNOSIS: Cancer of distal sigmoid colon.

GROSS DESCRIPTION

The specimen is received unfixed labeled "sigmoid colon and upper rectum" and consists of segment of large bowel measuring 56 cm. in length and 3 cm. in diameter. The distal 7 cm. of the specimen is beyond the peritoneal reflection. The rectal margin of resection is 3.7 cm. in diameter. There is abundant pericolic fat and the entire specimen is up to 17.5 cm. in diameter. The bowel is opened with a single incision on the antimesenteric surface. There is a fungating mucosal tumor measuring 3.2 x 2 x 0.5 cm. that is 3 cm. from the margin of resection and approximately 2 cm. beyond the peritoneal reflection. A portion of polyp is taken for research purposes. Sections after fixation and clearing.

BLOCK SUMMARY: 1 and 2 - margins of resection; 3-9 - tumor; 10-19 - pericolic lymph nodes.

MICROSCOPIC DESCRIPTION

Tumor type: Colonic adenocarcinoma.
Tumor grade: 2 out of 3
Tumor size: 3.2 cm.
Distance to nearest margin: 3 cm.
Level of penetration: Carcinoma penetrates into the muscularis propria but not through it.
Margins of resection: Negative for malignancy.

MICROSCOPIC DESCRIPTION

Vascular invasion: Absent.
Host response: Moderate acute and chronic inflammation.
Attached lymph nodes: There is no evidence of malignancy in any of 30 pericolic lymph nodes.
Non-lymph node pericolic tumor: Absent.
pTNM Stage: T2 N0
Other findings: None.

DIAGNOSIS

Sigmoid colon and upper rectum, segmental resection: Colonic adenocarcinoma.

Note: Carcinoma invades into but not through the muscularis propria. There is no evidence of malignancy in any of 30 pericolic lymph nodes.

Source: NCI Genomic Data Commons file 5957ab9e-1fd8-4e3d-8104-e7e57116c410 (TCGA-AF-2693.54C94271-4D50-4195-8709-FA4594D4C423.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).